Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3346, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3346-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Kidney, nephrectomy:

Tumor Characteristics:

1. Histologic type: Clear cell renal carcinoma.
2. Tumor site: Mid and lower pole.
3. Tumor size: 5.2 x 4.5 cm.
4. Macroscopic extent of tumor: Limited to kidney, does not penetrate capsule.
5. Nuclear grade: Fuhrman grade: 3/4.
6. Lymphovascular space invasion: Present.
7. Transcapsular invasion: No.
8. Renal vein invasion: No.
9. Vena caval invasion: Not resected.
10. Adrenal gland: Not resected.

Surgical Margin Status:

1. Soft tissue margins: Free of tumor.
2. Ureteral margin: Free of tumor.
- Vascular Margins: Free of tumor.

Staging code T1NXMX.

Electronic Signature

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Renal mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Left kidney

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in one container labeled [REDACTED] and left kidney and consists of a kidney with attached perinephric fat measuring 15.0 x 11.0 x 10.0 cm and weighs 543 grams. There is no adrenal gland attached to the specimen. The ureter stump measures 5.0 cm in length and 0.5 cm in diameter and is grossly unremarkable. The renal artery stump measures 1.0 cm in length and 0.9 cm in diameter and is grossly unremarkable. The renal vein stump measures 2.0 cm in length and 1.0 cm in diameter and is grossly unremarkable. The kidney is bisected and reveals a circumscribed golden yellow slightly hemorrhagic mass measuring 5.2 x 4.5 x 4.0 cm that is located within the mid to lower pole. The mass is located beneath the

[page 2 of 2]
capsular surface and does not appear to penetrate through the capsule into the surrounding perinephric fat. There is also a cyst adjacent to the mass that is subcapsular measuring 4.5 x 1.0 cm. The cyst lining is slightly trabecular and contains hemorrhagic material. The surrounding renal cortex is red-tan and measures 0.5 cm in greatest dimension and shows a well demarcated renal cortex and pyramids. Received with the specimen are three cassettes, one green, one yellow and one blue labeled [REDACTED]. Representative sections are submitted as follows: sections from mass-1 to 4: [REDACTED] renal artery and vein-5 sections from cyst in junction with mass-7 Low-magnification renal cortex-8 [REDACTED]

Source: NCI Genomic Data Commons file 5ecb1d77-e61d-4bb2-8e74-80945ddcf7f5 (TCGA-A3-3346.14FEBE79-6CF3-4AF9-8591-2D5ED15770BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).